MMRF case MMRF_1386 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/8b72ff50-1613-40d4-82ee-b84583002723

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 54.5 years (19,914 days); ISS stage: I; Days to last known disease status: 1,463 days (4.0 years); Days to last follow up: 1,463 days (4.0 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 8 days; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 177 days; Days to treatment end: 232 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 232 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -8 (ECOG 0): M Protein 2.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.93 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.57 mg/dL; Immunoglobulin G 37.5 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 3.3 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 2.96 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 8.5 g/dL; Glucose 5.17 mmol/L; C-Reactive Protein 0.123 mg/dL.
- Day 92 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 4.41 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.18 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 6 mmol/L.
- Day 177 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 4.61 g/L; Immunoglobulin A 0.5 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 8.1 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 33.7 ×10⁹/L; Absolute Neutrophil 30 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 150 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 260 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 5.1 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 5.01 mmol/L.
- Day 344 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 9.2 g/L; Immunoglobulin A 1.38 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 3.5 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 5.8 g/dL; Glucose 4.9 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 1.76 g/L; Immunoglobulin M 0.64 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 5.9 g/dL; Glucose 4.79 mmol/L.
- Day 541 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 2.17 g/L; Immunoglobulin M 0.63 g/L; Lactate Dehydrogenase 5.3 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 6.44 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 2.34 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 722 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.94 mg/dL; Immunoglobulin G 15.6 g/L; Immunoglobulin A 2.32 g/L; Immunoglobulin M 0.66 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 113 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.5 mmol/L.
- Day 820 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.79 mg/dL; Immunoglobulin G 15.1 g/L; Immunoglobulin A 2.56 g/L; Immunoglobulin M 0.58 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 35 g/L; Total Protein 6.5 g/dL; Glucose 5.06 mmol/L.
- Day 904 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.63 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 2.7 g/L; Immunoglobulin M 0.6 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 1,016 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 2.83 g/L; Immunoglobulin M 0.74 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 114 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 4.57 mmol/L.
- Day 1,107 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 2.68 g/L; Immunoglobulin M 0.69 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.63 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 4.62 mmol/L.
- Day 1,183 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.81 mg/dL; Immunoglobulin G 15 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.71 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 7 g/dL; Glucose 3.58 mmol/L.
- Day 1,267 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.85 mg/dL; Immunoglobulin G 17.2 g/L; Immunoglobulin A 2.96 g/L; Immunoglobulin M 0.7 g/L; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 34 g/L; Total Protein 6.8 g/dL; Glucose 3.96 mmol/L.
- Day 1,371 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.27 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 34 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 1,463 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 3.01 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 4.7 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 7.2 g/dL; Glucose 4.73 mmol/L.

Other clinical attributes
- Day -8: Weight: 81 kg; Height: 152 cm.

Biospecimens (2 samples)
- Sample MMRF_1386_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -8 days.
- Sample MMRF_1386_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -8 days.
